Somatic mutation profile of tumor specimen ALCH-ABRW-TTP1-A (aliquot ALCH-ABRW-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABRW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenosquamous carcinoma; Age at diagnosis: 53.0 years (19,343 days).
Specimen ALCH-ABRW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0985bb16-02b3-4df6-9bf0-aee5127b9000.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABRW-NB1-A (Blood Derived Normal), aliquot ALCH-ABRW-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6916c0b-4b2d-423f-bf64-5929ea598f43

The open-access MAF lists 112 somatic variants for this specimen: 70 protein-altering or splice-affecting, 27 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 27, Intron 7, Splice Region 5, Nonsense Mutation 4, RNA 4, 3'UTR 3, Frame Shift Ins 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 195/1035 reads (19%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 91/666 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>C p.T125= | Splice Region (SNP) | VAF 38/223 reads (17%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2965C>A p.H989N | Missense Mutation (SNP) | VAF 375/640 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs779913181, COSV51424228, COSV99273786; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1292G>A p.R431Q | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.1); catalogued as rs573938761; called by muse, mutect2, varscan2
- APLP1 | c.1402G>C p.D468H | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.661); catalogued as COSV99032556; called by muse, mutect2
- BCHE | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 102/530 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52257201; called by muse, varscan2
- BMI1 | c.25A>T p.I9F | Missense Mutation (SNP) | VAF 86/432 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV64959892; called by muse, mutect2, varscan2
- FOCAD | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.185); catalogued as COSV100619881; called by muse, mutect2, varscan2
- GTDC1 | c.273G>C p.E91D | Missense Mutation (SNP) | VAF 18/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99600088; called by muse, mutect2
- KCNQ2 | c.362G>C p.S121T | Missense Mutation (SNP) | VAF 31/305 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.437); catalogued as COSV60440208; called by muse, varscan2
- LARGE2 | c.442T>C p.W148R | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs770535694; called by muse, mutect2, varscan2
- MEPE | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 12/331 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100734995; called by muse, mutect2
- MYLK3 | c.2115A>T p.L705= | Splice Region (SNP) | VAF 111/423 reads (26%) | catalogued as rs369405932; called by muse, mutect2, varscan2
- NME8 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 88/551 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV52249742, COSV99554010; called by muse, mutect2, varscan2
- OR5T1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 61/412 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); catalogued as COSV57302128; called by muse, mutect2, varscan2
- PCDH10 | c.2528C>A p.S843* | Nonsense Mutation (SNP) | VAF 32/332 reads (10%) | catalogued as COSV52100198; called by muse, mutect2, varscan2
- PCDHB14 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782159115; called by muse, mutect2, varscan2
- PPARGC1B | c.2458G>A p.D820N | Missense Mutation (SNP) | VAF 40/340 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs147457894; called by muse, varscan2
- PRKCH | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.014); catalogued as rs1417926976; called by muse, mutect2, varscan2
- RGS18 | c.117C>A p.I39= | Splice Region (SNP) | VAF 16/98 reads (16%) | catalogued as COSV66507062, COSV66510135; called by muse, mutect2, varscan2
- S1PR1 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59513597, COSV59514436; called by muse, mutect2
- SNX16 | c.593A>G p.H198R | Missense Mutation (SNP) | VAF 36/209 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs910044628; called by muse, mutect2, varscan2
- TTC37 | c.4504C>T p.R1502W | Missense Mutation (SNP) | VAF 56/471 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372395062; called by muse, mutect2, varscan2
- TTC6 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as rs745759551; called by mutect2, varscan2
- USH2A | c.8264T>A p.L2755H | Missense Mutation (SNP) | VAF 33/584 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.357); catalogued as COSV56368478; called by muse, mutect2
- VCAN | c.2020C>A p.P674T | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs1218239923; called by muse, mutect2, varscan2
- AASS | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- ALPL | c.338C>G p.T113S | Missense Mutation (SNP) | VAF 30/267 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- ANKRD28 | c.2783+3G>C | Splice Region (SNP) | VAF 65/316 reads (21%) | called by muse, mutect2, varscan2
- AOAH | c.45G>T p.L15F | Missense Mutation (SNP) | VAF 125/704 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- APEH | c.1728T>A p.F576L | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF4 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 68/331 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ARHGEF9 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ATXN7 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BNC2 | c.1045G>A p.G349R | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- C1QTNF7 | c.349C>G p.P117A | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.116); called by muse, mutect2
- CALY | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2
- CAPN13 | c.1254C>G p.F418L | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2
- CCDC18 | c.1750G>A p.E584K (on ENST00000343253 / NM_001306076.1; = p.E585K on NM_206886.4) | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- CFHR2 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 132/598 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CHCHD2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- DMTN | c.730-2A>T p.X244_splice | Splice Site (SNP) | VAF 21/168 reads (13%) | called by muse, varscan2
- ESPN | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ESPN | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EYS | c.4616del p.T1539Kfs*11 | Frame Shift Del (DEL) | VAF 146/535 reads (27%) | called by mutect2, pindel, varscan2
- GOLGB1 | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2
- HCN4 | c.1477T>A p.W493R | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ING1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- KAT6A | c.4112T>C p.L1371P | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT34 | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 63/647 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- LRRD1 | c.1694G>T p.C565F | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- MAML1 | c.2149A>T p.N717Y | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- NPHP3 | c.3044C>G p.S1015* | Nonsense Mutation (SNP) | VAF 26/634 reads (4%) | called by muse, mutect2
- NSMCE3 | c.357C>A p.Y119* | Nonsense Mutation (SNP) | VAF 28/344 reads (8%) | called by muse, mutect2
- OR10W1 | c.830del p.N277Tfs*7 | Frame Shift Del (DEL) | VAF 15/114 reads (13%) | called by mutect2, pindel, varscan2
- OR56A3 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 49/497 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PGK2 | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 75/599 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- PLCD3 | c.1827G>C p.L609= | Splice Region (SNP) | VAF 10/46 reads (22%) | called by muse, varscan2
- PTPRF | c.1951G>T p.G651C | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAD54B | c.2320A>G p.I774V | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- ROR1 | c.2048G>A p.W683* | Nonsense Mutation (SNP) | VAF 52/226 reads (23%) | called by muse, mutect2, varscan2
- RPL11 | c.405G>T p.R135S (on ENST00000374550 / NM_001199802.1; = p.R136S on NM_000975.5) | Missense Mutation (SNP) | VAF 114/642 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TENT5B | c.145dup p.L49Pfs*70 | Frame Shift Ins (INS) | VAF 26/182 reads (14%) | called by mutect2, pindel, varscan2
- VARS2 | c.2112G>C p.K704N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ZNF140 | c.186dup p.E63Rfs*22 | Frame Shift Ins (INS) | VAF 31/296 reads (10%) | called by mutect2, pindel, varscan2
- ZNF283 | c.663A>C p.K221N | Missense Mutation (SNP) | VAF 68/644 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- ZNF436 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ZNF470 | c.1689G>T p.K563N | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF850 | c.1183T>A p.C395S | Missense Mutation (SNP) | VAF 56/487 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADPRH | c.366C>T p.F122= | Silent (SNP) | VAF 33/189 reads (17%) | called by muse, mutect2, varscan2
- AHDC1 | c.1380G>T p.V460= | Silent (SNP) | VAF 41/199 reads (21%) | called by muse, varscan2
- ATP8A2 | c.405G>A p.E135= | Silent (SNP) | VAF 43/399 reads (11%) | catalogued as COSV54971857; called by muse, mutect2, varscan2
- BCHE | c.408T>C p.T136= | Silent (SNP) | VAF 98/529 reads (19%) | called by muse, varscan2
- COL13A1 | c.1293C>A p.P431= (on ENST00000398978 / NM_001130103.2; = p.P374= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- CUL4A | c.429C>T p.C143= (on ENST00000375440 / NM_001008895.4; = p.C43= on NM_003589.3) | Silent (SNP) | VAF 22/280 reads (8%) | called by muse, mutect2
- ERCC6L | c.1605C>T p.T535= | Silent (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- FARS2 | c.324G>A p.P108= | Silent (SNP) | VAF 104/560 reads (19%) | catalogued as rs139618748; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT3 | c.2565C>A p.A855= | Silent (SNP) | VAF 74/420 reads (18%) | called by muse, mutect2, varscan2
- GLIS2 | c.1482C>T p.V494= | Silent (SNP) | VAF 52/346 reads (15%) | called by muse, mutect2, varscan2
- HIPK3 | c.2001A>G p.R667= | Silent (SNP) | VAF 45/265 reads (17%) | called by muse, mutect2, varscan2
- HSPA9 | c.957C>G p.L319= | Silent (SNP) | VAF 32/858 reads (4%) | called by muse, mutect2
- IFT80 | c.837C>T p.I279= | Silent (SNP) | VAF 73/372 reads (20%) | catalogued as rs750697170; called by muse, mutect2, varscan2
- MYO15A | c.930C>T p.D310= | Silent (SNP) | VAF 29/212 reads (14%) | catalogued as rs774380947, COSV52757868; called by muse, mutect2, varscan2
- NRXN1 | c.627C>G p.P209= | Silent (SNP) | VAF 13/83 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.11454G>T p.T3818= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV52765516; called by muse, mutect2, varscan2
- PAPOLG | c.1413C>T p.N471= | Silent (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- PCDHB8 | c.1296G>A p.L432= | Silent (SNP) | VAF 126/2796 reads (5%) | catalogued as rs1366182181; called by muse, mutect2
- PGGHG | c.1972C>T p.L658= | Silent (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- PPDPFL | c.52C>A p.R18= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV57461760; called by muse, mutect2, varscan2
- PPEF2 | c.315T>C p.Y105= | Silent (SNP) | VAF 46/484 reads (10%) | called by muse, mutect2
- RAB11FIP1 | c.660A>G p.L220= | Silent (SNP) | VAF 40/307 reads (13%) | called by muse, mutect2, varscan2
- SETD1A | c.981C>T p.I327= | Silent (SNP) | VAF 48/394 reads (12%) | catalogued as rs1220499465, COSV99352866; called by muse, mutect2, varscan2
- SYTL5 | c.1734G>A p.K578= | Silent (SNP) | VAF 34/148 reads (23%) | called by muse, mutect2
- TCHH | c.2193C>T p.R731= | Silent (SNP) | VAF 37/136 reads (27%) | called by muse, mutect2, varscan2
- TENT4A | c.2157G>A p.P719= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs746633129, COSV50100953; called by muse, varscan2
- TRIM49 | c.1329C>G p.L443= | Silent (SNP) | VAF 17/238 reads (7%) | called by muse, varscan2
- ABCA11P | n.1061C>G | RNA (SNP) | VAF 44/541 reads (8%) | catalogued as COSV101482773; called by muse, mutect2
- ABI3BP | c.1577-9229T>C | Intron (SNP) | VAF 45/338 reads (13%) | called by muse, mutect2, varscan2
- AC104472.1 | n.330A>T | RNA (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- AOPEP | c.2319+16C>T | Intron (SNP) | VAF 30/237 reads (13%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29700852 T>C | 3'Flank (SNP) | VAF 34/351 reads (10%) | called by muse, mutect2
- CUBN | c.4696-11405C>T | Intron (SNP) | VAF 37/184 reads (20%) | called by muse, mutect2, varscan2
- DCHS2 | n.1833C>T | RNA (SNP) | VAF 30/353 reads (8%) | called by muse, mutect2
- GALK2 | c.*407T>C | 3'UTR (SNP) | VAF 38/280 reads (14%) | called by muse, mutect2, varscan2
- GH2 | c.457-114A>G | Intron (SNP) | VAF 12/295 reads (4%) | called by muse, mutect2
- HP | c.5+64A>T | Intron (SNP) | VAF 354/988 reads (36%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.55G>T | RNA (SNP) | VAF 75/607 reads (12%) | called by muse, mutect2, varscan2
- NT5DC3 | c.1189-215T>A | Intron (SNP) | VAF 71/377 reads (19%) | called by muse, mutect2, varscan2
- SYNE1 | c.12528+17C>T | Intron (SNP) | VAF 22/478 reads (5%) | called by muse, mutect2
- VPS13A | c.*8C>G | 3'UTR (SNP) | VAF 70/676 reads (10%) | called by muse, mutect2
- ZNF487 | c.*1134C>T | 3'UTR (SNP) | VAF 26/232 reads (11%) | called by muse, mutect2, varscan2
